Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CR, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CR-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: F

HCN:

Ordering

MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Parathyroid: Right Upper
2. Parathyroid: Left lower parathyroid
3. Lymph node: Left paratracheal node
4. Thyroid: Total thyroid, stitch marks upper pole right lobe

Diagnosis

1. No pathological diagnosis: Parathyroid (right upper) biopsy.
2. No pathological diagnosis: Parathyroid (left lower) biopsy.
3. Follicular nodular disease: Thyroid (left paratracheal region) biopsy.
4. Multifocal papillary carcinoma, dominant 2.6 cm, follicular variant, right: Thyroid
No pathological diagnosis: Lymph nodes, 3
No pathological diagnosis: Parathyroid, right x2, left
Total thyroidectomy specimen.

Synoptic Data

Procedure:

Received:

Specimen Integrity:

Specimen Size:

Total thyroidectomy

Fresh

Intact

Right lobe:

5.0 cm

3.5 cm

2.0 cm

Left lobe:

4.0 cm

2.4 cm

1.5 cm

Isthmus +/- pyramidal lobe:

ICD-0-3

carcinoma, papillary,
follicular variant 8340/3

Site: thyroid, NOS C73.9 1w6/10/11

[page 2 of 4]
3.4 cm
2.3 cm
1.0 cm
Specimen Weight: 24.2 g
Tumor Focality: Multifocal, bilateral
----- DOMINANT TUMOR -----
Tumor Laterality: ~~Left lobe~~
Tumor Size: Greatest dimension: 2.6cm
Additional dimension: 2.4 cm
Additional dimension: 2.2 cm
Histologic Type: ~~Papillary carcinoma, follicular variant~~ *pvt TSS, follicular variant = 100%*
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: Totally encapsulated
Tumor Capsular Invasion: Present, extent minimal
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
----- SECOND TUMOR -----
Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 0.1cm
Histologic Type: Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Tumor Capsule: None
Tumor Capsular Invasion: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 3
Number of regional lymph nodes involved: 0
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Parathyroid gland(s), within normal limits

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

verified by:

Clinical History

[page 3 of 4]
for qs

Gross Description

1. The specimen labeled with the patient's name and as "Right Upper" contains a piece of tissue that measures 0.3 x 0.2 x 0.05 cm. It is frozen for intraoperative consultation.

1A frozen tissue resubmitted

2. The specimen labeled with the patient's name and as "Left Lower Parathyroid for QS" contains a piece of tissue that measures 0.4 x 0.2 x 0.1 cm. It is frozen for intraoperative consultation.

2A frozen tissue resubmitted

3. The specimen labelled with the patient's name and as "Left Paratracheal Node" consists of a piece of brown tissue that measures 0.7 x 0.6 x 0.3 cm.

3A submitted in toto

4. The specimen labeled with the patient's name and as "Total Thyroid, Stitch Marks Upper Pole Right Lobe" consists of a thyroid gland that is oriented with a suture and weighs 24.2 g. The right lobe measures 5.0 cm SI x 3.5 cm ML x 2.0 cm AP, the left lobe measures 4.0 cm SI x 2.4 cm ML x 1.5 cm AP and the isthmus measures 3.4 cm SI x 2.3 cm ML x 1.0 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with blue dye. The mid to lower right lobe contains a well delineated nodule that measures 2.6 cm SI x 2.4 cm ML x 2.2 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of the nodule and normal tissue are stored frozen. The remainder of the specimen is submitted in toto as follows:

4A-M right lobe, superior to inferior [E-F;G-H;J-K section bisected]

4N-Q isthmus

4R-V left lobe, superior to inferior

[page 4 of 4]
Quick Section Diagnosis

1. Parathyroid: Right Upper QS: Parathyroid tissue identified.
Surgeon informed at

2. Parathyroid: Left lower parathyroid: Parathyroid tissue identified.
Surgeon called at

Source: NCI Genomic Data Commons file 2a5e3b56-5e6e-4486-a76d-789dbd257b93 (TCGA-EM-A2CR.9E95A9A3-0E7C-462A-8C9C-8005161A918B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).